Somatic mutation profile of tumor specimen 8dd1d8be-dc7e-44f5-9f44-77ecf0 (aliquot 8dd1d8be-dc7e-44f5-9f44-77ecf0_D6_1) from CPTAC case 11BR019, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.7 years (22,173 days).
Specimen 8dd1d8be-dc7e-44f5-9f44-77ecf0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4459d5b3-5606-4791-8140-314c01032cd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0819e79c-6e11-4c5a-826b-6a3de0 (Blood Derived Normal), aliquot 0819e79c-6e11-4c5a-826b-6a3de0_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cfbfd1e-b957-4c9d-901b-04c78b7c82dd

The open-access MAF lists 71 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Intron 3, Nonsense Mutation 3, 5'UTR 2, RNA 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K4 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62254942, COSV62259088; called by muse, mutect2, varscan2
- AC005324.2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); catalogued as rs375375292, COSV60886616; called by muse, mutect2, varscan2
- AGL | c.3790G>A p.G1264R | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99648404; called by muse, mutect2, varscan2
- CNGA3 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); catalogued as rs1289044362; called by muse, mutect2, varscan2
- FGF5 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs756574088; called by muse, mutect2, varscan2
- GABRA1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as rs755336024, COSV50108949, COSV99196150; called by muse, mutect2, varscan2
- MPP4 | c.1257C>A p.Y419* | Nonsense Mutation (SNP) | VAF 29/162 reads (18%) | catalogued as rs1461002383; called by muse, mutect2, varscan2
- NOC4L | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as rs755207814; called by muse, mutect2, varscan2
- PCLO | c.8911G>A p.D2971N | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232051066, COSV61647755; called by muse, mutect2, varscan2
- POR | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 29/365 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1466070141, COSV58694568; called by muse, mutect2
- PPP1R1A | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752832666, COSV57742235; called by muse, mutect2, varscan2
- STK36 | c.1891C>T p.Q631* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | catalogued as rs1230249224, COSV55328093; called by muse, mutect2, varscan2
- TPO | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs1430829526; called by muse, mutect2
- ABCA13 | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ANKRD34A | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2
- ARHGAP4 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP6V0A4 | c.1603T>G p.F535V | Missense Mutation (SNP) | VAF 25/358 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCNO | c.785C>A p.A262E | Missense Mutation (SNP) | VAF 68/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL11A1 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- EMILIN1 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- EPHB1 | c.1990G>C p.D664H | Missense Mutation (SNP) | VAF 55/409 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT1 | c.9077C>T p.T3026I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.118); called by muse, mutect2
- FCAMR | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- FSTL5 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GATA3 | c.1305dup p.S436Lfs*71 | Frame Shift Ins (INS) | VAF 19/138 reads (14%) | called by mutect2, pindel, varscan2
- IGLV1-50 | c.39C>A p.H13Q | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- KCNB2 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMNA | c.1290C>G p.F430L | Missense Mutation (SNP) | VAF 85/593 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARK2 | c.1145A>C p.D382A | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- MUC17 | c.6491C>G p.T2164R | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- PLCL2 | c.734G>A p.G245E (on ENST00000615277 / NM_001144382.2; = p.G119E on NM_015184.5) | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHM2 | c.1643A>G p.E548G | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); called by muse, mutect2
- PTPRO | c.1267+1G>A p.X423_splice | Splice Site (SNP) | VAF 34/248 reads (14%) | called by muse, mutect2, varscan2
- RHCG | c.336C>A p.F112L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RYR1 | c.6031C>G p.Q2011E | Missense Mutation (SNP) | VAF 46/618 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- SLC28A1 | c.414G>C p.R138S | Missense Mutation (SNP) | VAF 55/565 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by mutect2, varscan2
- STX18 | c.100A>T p.S34C | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2
- TAF7 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 33/239 reads (14%) | called by muse, mutect2, varscan2
- TCTN3 | c.1450T>C p.S484P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.454); called by muse, mutect2
- TDRD1 | c.1361C>G p.S454C | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- TMEM132C | c.2330A>T p.E777V | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TMEM233 | c.173T>A p.V58D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- TMIGD3 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- TRIM64B | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 82/1034 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2
- TRIO | c.8786A>T p.K2929M | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.866); called by muse, mutect2
- TTN | c.67715C>T p.P22572L (on ENST00000591111; = p.P15148L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT8 | c.239C>A p.T80N | Missense Mutation (SNP) | VAF 58/370 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- ZFP2 | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF784 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.353); called by muse, mutect2
- ADGRL2 | c.630T>C p.T210= | Silent (SNP) | VAF 61/382 reads (16%) | called by muse, mutect2, varscan2
- CIT | c.3730C>A p.R1244= | Silent (SNP) | VAF 15/107 reads (14%) | called by mutect2, varscan2
- FBXL18 | c.1260G>A p.L420= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs1169221725; called by muse, mutect2, varscan2
- FLG | c.1563G>A p.G521= | Silent (SNP) | VAF 143/1127 reads (13%) | catalogued as rs763639841; called by muse, mutect2, varscan2
- HIVEP1 | c.2427A>T p.I809= | Silent (SNP) | VAF 59/373 reads (16%) | called by muse, mutect2, varscan2
- MSLNL | c.1932G>A p.L644= | Silent (SNP) | VAF 37/319 reads (12%) | catalogued as rs1192154595; called by muse, mutect2, varscan2
- NBPF11 | c.2049G>T p.V683= | Silent (SNP) | VAF 27/1016 reads (3%) | called by muse, mutect2
- PLEKHG2 | c.2688T>A p.A896= | Silent (SNP) | VAF 16/417 reads (4%) | called by muse, mutect2
- PPP1R1A | c.93G>A p.R31= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- RIMBP2 | c.1110C>T p.C370= | Silent (SNP) | VAF 30/536 reads (6%) | catalogued as rs373258246; called by muse, mutect2
- THAP1 | c.636A>G p.P212= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- TRIM50 | c.531C>T p.R177= | Silent (SNP) | VAF 46/376 reads (12%) | catalogued as rs1194371507; called by muse, mutect2, varscan2
- USP36 | c.33G>C p.L11= | Silent (SNP) | VAF 71/367 reads (19%) | called by muse, mutect2, varscan2
- ZNF701 | c.1035C>T p.F345= (on ENST00000301093; = p.F279= on NM_018260.3) | Silent (SNP) | VAF 48/471 reads (10%) | catalogued as rs751637985, COSV56525862, COSV99991063; called by muse, mutect2, varscan2
- ZNF790 | c.447C>A p.P149= | Silent (SNP) | VAF 29/288 reads (10%) | called by muse, mutect2, varscan2
- AC027559.1 | n.352G>T | RNA (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- CCNYL2 | n.1002C>A | RNA (SNP) | VAF 30/169 reads (18%) | called by muse, mutect2, varscan2
- CHL1 | c.-2C>A | 5'UTR (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- DNAH14 | c.3051+11446C>T | Intron (SNP) | VAF 25/148 reads (17%) | catalogued as rs978026032, COSV100145006; called by muse, mutect2, varscan2
- IP6K3 | c.-5C>T | 5'UTR (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- IPO11 | c.-7+6160G>C | Intron (SNP) | VAF 14/242 reads (6%) | catalogued as rs1294897933; called by muse, mutect2
- RAD52 | c.467+251C>T | Intron (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
